Gene-level copy-number profile of tumor specimen TCGA-14-0812-01B from TCGA case TCGA-14-0812, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 65.9 years (24,085 days).
Specimen TCGA-14-0812-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-GBM.e7ceb967-44a5-4ab3-8f64-8bf2aa89316e.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-14-0812-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/abc81c72-e16d-4019-90cd-81404a5d7d49

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 24; copy number 2: 7,642; copy number 3: 6,738; copy number 4: 40,751; copy number 5: 4,162; copy number 6: 10; copy number 7: 36; copy number 8: 64; copy number 10: 11; copy number 11: 1; copy number 12: 50; copy number 13: 9; copy number 15: 82; copy number 18: 54; copy number 19: 3; copy number 20: 46; copy number 22: 22; copy number 23: 36; copy number 25: 8; copy number 31: 25; copy number 34: 6; copy number 41: 34.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-14-0812-01B-01D-0591-01): tumor purity 0.66, ploidy 1.92, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 387 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:176,415,439–189,325,304, 267 genes, copy number 10–41 (broad region; genes not listed).
- chr3:189,645,327–189,645,466, 1 gene, copy number 11: AC078809.1.
- chr4:51,843,000–57,353,329, 119 genes, copy number 12–23 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 24. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
